Somatic mutation profile of tumor specimen HTMCP-03-06-02342-01A (aliquot HTMCP-03-06-02342-01A-01D-9392) from CGCI case HTMCP-03-06-02342, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 58.9 years (21,497 days).
Specimen HTMCP-03-06-02342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6dd6e5dd-5947-4408-83ee-e0ece8408bd8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02342-10A (Blood Derived Normal), aliquot HTMCP-03-06-02342-10A-01D-9392; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d16aa81a-69c6-4b6a-bf4c-b155d33fa5b0

The open-access MAF lists 117 somatic variants for this specimen: 81 protein-altering or splice-affecting, 31 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 31, Nonsense Mutation 9, 5'Flank 2, Splice Region 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 26/183 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, varscan2
- FBXW7 | c.1436G>C p.R479P (on ENST00000281708 / NM_001349798.2; = p.R399P on NM_018315.5) | Missense Mutation (SNP) | VAF 18/134 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA4 | c.6769G>A p.D2257N | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1327249006, COSV64672419; called by muse, mutect2
- ADGRV1 | c.8503G>A p.V2835M | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs376761306; called by muse, mutect2, varscan2
- AL592490.1 | c.870C>G p.I290M | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69426297; called by muse, mutect2, varscan2
- ALPK3 | c.4344C>G p.S1448R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs758620638; called by muse, mutect2, varscan2
- ASXL3 | c.3349C>G p.R1117G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV52463509; called by muse, mutect2
- BLM | c.25C>G p.L9V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61924017; called by mutect2, varscan2
- BTN2A2 | c.792G>T p.W264C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as rs1038324367; called by muse, varscan2
- CCT3 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.088); catalogued as COSV55290911; called by muse, mutect2, varscan2
- CFAP46 | c.7097G>A p.R2366H | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as rs138288778; called by muse, mutect2, varscan2
- CHD8 | c.3389G>A p.R1130H (on ENST00000646647 / NM_001170629.2; = p.R851H on NM_020920.4) | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs765025620, COSV67872377; called by muse, mutect2, varscan2
- CIP2A | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.136); catalogued as COSV55417640; called by muse, mutect2, varscan2
- CNTNAP2 | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1186551916, COSV62252736; called by muse, mutect2, varscan2
- COL3A1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as COSV58584507; called by mutect2, varscan2
- CRYBG3 | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV101370629; called by muse, mutect2, varscan2
- CWC22 | c.2594G>C p.R865T | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV99844307; called by muse, mutect2, varscan2
- DNAJC13 | c.6109G>A p.A2037T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs918042561; called by muse, mutect2
- DOCK10 | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.784); catalogued as rs754552663; called by muse, varscan2
- HCN1 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57501369, COSV57539260; called by muse, mutect2, varscan2
- ITPRID1 | c.1079G>A p.R360K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV60072313, COSV60081135; called by muse, mutect2, varscan2
- KIF5C | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.49); catalogued as COSV68482793; called by muse, mutect2, varscan2
- KIT | c.1671G>A p.W557* | Nonsense Mutation (SNP) | VAF 17/141 reads (12%) | catalogued as COSV55392798, COSV55404753, COSV55418401; called by muse, mutect2, varscan2
- KPNA5 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 17/126 reads (13%) | catalogued as COSV62651065, COSV62652142; called by muse, mutect2, varscan2
- MYO3B | c.606C>G p.V202= | Splice Region (SNP) | VAF 12/87 reads (14%) | catalogued as COSV58709682; called by muse, mutect2, varscan2
- PBX3 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV60730066; called by muse, mutect2, varscan2
- PDYN | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54102535; called by muse, mutect2, varscan2
- RPGRIP1 | c.2264G>A p.R755H | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs754461580, COSV52849598; called by muse, mutect2, varscan2
- SAMD9 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66076625; called by muse, mutect2, varscan2
- SLC44A5 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV63773547; called by muse, mutect2
- TBL1X | c.1260G>A p.W420* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as COSV54284900; called by muse, mutect2, varscan2
- THSD7A | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774611290, COSV70260421, COSV70267749; called by muse, mutect2, varscan2
- TPM2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.426); catalogued as COSV61405532; called by muse, mutect2
- USH2A | c.13155G>C p.K4385N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV56372897, COSV56385873; called by muse, mutect2, varscan2
- WDFY3 | c.303A>G p.T101= | Splice Region (SNP) | VAF 42/128 reads (33%) | catalogued as rs1413995130; called by muse, mutect2, varscan2
- ZZEF1 | c.4589G>A p.R1530Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs747994240; called by mutect2, varscan2
- AFF3 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- AMOT | c.3040C>G p.P1014A (on ENST00000371959 / NM_001113490.1; = p.P605A on NM_133265.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASXL3 | c.3629C>T p.S1210L | Missense Mutation (SNP) | VAF 21/168 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP290 | c.4264G>T p.D1422Y | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CFH | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2
- CHD6 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- CLASP1 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- CPS1 | c.4498G>C p.A1500P | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- CRX | c.761C>G p.S254* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- DDX43 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DOCK10 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.03); called by muse, varscan2
- DRP2 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- EGFLAM | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2
- ELAPOR1 | c.2246C>T p.T749I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FGFR1 | c.1486G>A p.E496K (on ENST00000447712 / NM_023110.3; = p.E494K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- GPRASP1 | c.3800C>A p.T1267N | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR5B | c.5972C>G p.S1991C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- KBTBD12 | c.762C>G p.F254L | Missense Mutation (SNP) | VAF 41/364 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KDM3A | c.3622C>T p.H1208Y | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF24 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- KNTC1 | c.4810T>C p.F1604L | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MAGED1 | c.741G>C p.K247N | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MED14 | c.1684A>G p.T562A | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MEGF8 | c.7265A>T p.Y2422F (on ENST00000251268 / NM_001271938.2; = p.Y2355F on NM_001410.3) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH15 | c.5231C>A p.A1744D | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MYO5A | c.4963G>T p.D1655Y | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by mutect2, varscan2
- NPY5R | c.1083G>C p.K361N | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- PLCE1 | c.6373G>A p.D2125N | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PRPF8 | c.4687C>T p.H1563Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RAI1 | c.2762C>T p.S921L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAI1 | c.3644C>G p.S1215C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- REST | c.3115C>A p.P1039T | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RLF | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RPS6KA3 | c.1301C>G p.S434C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2
- SFSWAP | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- SLC26A8 | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TBC1D25 | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- TEP1 | c.2179G>T p.D727Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.031); called by muse, varscan2
- TEP1 | c.1258C>T p.Q420* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- TLR8 | c.2335G>A p.D779N (on ENST00000218032 / NM_138636.5; = p.D797N on NM_016610.4) | Missense Mutation (SNP) | VAF 38/439 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2
- TTI1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 53/330 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- YWHAE | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF707 | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ZSCAN4 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM15 | c.1771C>T p.L591= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV55126854; called by muse, mutect2
- AGBL5 | c.1629G>A p.P543= | Silent (SNP) | VAF 24/136 reads (18%) | catalogued as rs769821257; called by muse, mutect2, varscan2
- CDC5L | c.1170T>C p.S390= | Silent (SNP) | VAF 29/164 reads (18%) | called by muse, mutect2, varscan2
- CELSR1 | c.6501G>A p.E2167= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as rs1175012812; called by muse, mutect2
- COL6A2 | c.291C>T p.G97= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs1007921670, COSV55999679; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF2RA | c.1170C>T p.R390= | Silent (SNP) | VAF 57/238 reads (24%) | catalogued as rs770943329, COSV62623858; called by muse, mutect2, varscan2
- DBH | c.273C>T p.D91= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- DNAH12 | c.8496C>T p.F2832= (on ENST00000351747; = p.F3700= on NM_001366028.2) | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as rs532300604, COSV61058612; called by muse, mutect2, varscan2
- FAM186A | c.2007C>T p.L669= | Silent (SNP) | VAF 20/185 reads (11%) | catalogued as rs1166449702; called by muse, mutect2, varscan2
- FAM47C | c.1080G>A p.E360= | Silent (SNP) | VAF 27/276 reads (10%) | called by muse, mutect2, varscan2
- FAM47C | c.2865A>G p.E955= | Silent (SNP) | VAF 152/409 reads (37%) | catalogued as COSV63724263; called by muse, mutect2, varscan2
- FLNA | c.6915C>T p.Y2305= (on ENST00000369850 / NM_001110556.2; = p.Y2297= on NM_001456.3) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs781910090, CM012748; called by muse, mutect2, varscan2
- GCN1 | c.4656C>G p.V1552= | Silent (SNP) | VAF 11/58 reads (19%) | called by muse, mutect2, varscan2
- GREB1 | c.1203C>T p.V401= | Silent (SNP) | VAF 9/95 reads (9%) | catalogued as rs765676056; called by muse, mutect2, varscan2
- GTF3C5 | c.708G>A p.Q236= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- INTS6L | c.630G>C p.V210= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- IPO4 | c.618G>A p.L206= | Silent (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- KCNA4 | c.1599C>T p.I533= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as COSV100068559; called by muse, mutect2, varscan2
- KCNA4 | c.18G>A p.V6= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- KRT76 | c.1809C>A p.G603= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- MTHFD1L | c.2175C>T p.N725= | Silent (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- NBPF12 | c.2346C>T p.L782= | Silent (SNP) | VAF 44/650 reads (7%) | catalogued as COSV58772388; called by muse, mutect2
- PCDHA11 | c.1323C>T p.S441= | Silent (SNP) | VAF 22/135 reads (16%) | catalogued as COSV56498089; called by muse, mutect2, varscan2
- PHKA2 | c.3354C>T p.I1118= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- RTL1 | c.3006G>A p.R1002= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV66017397; called by muse, mutect2, varscan2
- SORCS1 | c.1956C>T p.F652= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- TEP1 | c.2187G>A p.L729= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99403802; called by muse, varscan2
- TLN1 | c.606G>A p.Q202= | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- UBE3B | c.1440G>A p.Q480= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1332C>T p.V444= | Silent (SNP) | VAF 17/124 reads (14%) | catalogued as rs768918284; called by muse, mutect2, varscan2
- ZNF407 | c.2010C>T p.N670= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs755384720; called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915321 G>A | 5'Flank (SNP) | VAF 14/85 reads (16%) | catalogued as rs1228313232; called by muse, mutect2, varscan2
- CPLANE1 | c.*2407G>A | 3'UTR (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- FRG1 | chr4:189940518 G>A | 5'Flank (SNP) | VAF 20/141 reads (14%) | called by muse, mutect2, varscan2
- NF1 | c.5813-157C>G | Intron (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- UCKL1 | c.114-4188C>T | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as rs1180884301; called by muse, mutect2
